Somatic mutation profile of tumor specimen TCGA-AB-2959-03A (aliquot TCGA-AB-2959-03A-01W-0733-08) from TCGA case TCGA-AB-2959, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.5 years (26,114 days).
Specimen TCGA-AB-2959-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d2a6bd-ec41-46b8-8ac0-8bfcf8151b48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2959-11A (Solid Tissue Normal), aliquot TCGA-AB-2959-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db033c3c-d870-431c-901c-07ee777608d2

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- APOB | c.4342G>A p.V1448I | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV51941240; called by muse, mutect2, varscan2
- AQP5 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52230792; called by muse, mutect2, varscan2
- CCDC24 | c.599C>A p.A200E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1283414258, COSV62211170; called by muse, mutect2, varscan2
- DEUP1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.095); catalogued as rs201772678, COSV53213628; called by muse, mutect2, varscan2
- DOCK5 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs751838448, COSV52400400; called by muse, mutect2, varscan2
- GZMB | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs767137056, COSV53542092, COSV99362147; called by muse, mutect2, varscan2
- ITIH4 | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1422997587, COSV99819010; called by muse, mutect2
- KNL1 | c.4208G>C p.G1403A (on ENST00000346991 / NM_170589.5; = p.G1377A on NM_144508.5) | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.854); catalogued as COSV61156769; called by muse, mutect2, varscan2
- NUP93 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV57431755; called by muse, mutect2, varscan2
- PABPC3 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55802387; called by muse, varscan2
- PDS5B | c.3562A>G p.T1188A | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.109); catalogued as COSV59729562; called by muse, mutect2, varscan2
- PHF6 | c.586-1G>T p.X196_splice (on ENST00000332070 / NM_032458.3; = p.X197_splice on NM_032335.3) | Splice Site (SNP) | VAF 49/93 reads (53%) | catalogued as COSV100136238, COSV59703967; called by muse, mutect2, varscan2
- RIMS1 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750178485, COSV53438688; called by muse, mutect2, varscan2
- RTN4RL1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373384654; called by muse, varscan2
- SLCO5A1 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.202); catalogued as COSV52662016; called by muse, mutect2, varscan2
- TPO | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs1292427992, COSV61104710; called by muse, mutect2, varscan2
- ZBTB33 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 71/80 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782465723, COSV58534389; called by muse, mutect2, varscan2
- CEBPE | c.834G>T p.G278= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV52830141; called by mutect2, varscan2
- GLB1L2 | c.1812C>T p.S604= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs185917496, COSV100335204; called by muse, mutect2, varscan2
- MYOM3 | c.456C>T p.R152= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs368906169; called by muse, mutect2, varscan2
- SCUBE2 | c.366C>T p.D122= | Silent (SNP) | VAF 114/264 reads (43%) | catalogued as rs369076752; called by muse, mutect2, varscan2
